Surgical pathology report (de-identified scan), TCGA case TCGA-06-0142, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0142-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

MRN:

Birth Date:

Sex: Male Room/Bed:

PATH. NO:

NAME: [REDACTED]

MED. REC. NO:

AGE/SEX: M DOB:

SURGERY DATE:

PATIENT PHONE NO.:

RECEIVE DATE:

PHYSICIAN
COPY TO:

UPDATED REPORT

PATHOLOGICAL DIAGNOSIS:LEFT TEMPORAL LOBE: GLIOBLASTOMA MULTIFORME.

Operation/Specimen: UPDATED REPORT - Left temporal brain

Clinical History and Pre-Op Dx: Tumor

GROSS PATHOLOGY:

SPECIMEN: Left temporal brain tumor

FIXATIVE: Formalin

GENERAL: 3 x 1.5 x 1.5 cm aggregate of brain parenchyma. Cut section
shows an area of hemorrhage 0.8 cm in greatest dimension.

SECTIONS: 1-4- all submitted.

MICROSCOPIC: Sections show a high grade glioma with hypercellularity,
cellular pleomorphism, mitotic figures, capillary proliferation and
patchy areas of palisading necrosis. Portions of uninvolved brain
parenchyma is also present.ADDENDUM: MIB-1 stain shows that the proliferation index of the tumor
cells is about 20%.

TISSUE COMMITTEE CODE:

ICD9: 191.2

BILLING CODES:

[page 2 of 2]
Patient Name:

MRN:

Birth Date:

Sex: Male Room/Bed:

PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX: M DOB:

SURGERY DATE:

PATIENT PHONE NO.:

RECEIVE DATE:

PHYSICIAN:

COPY TO:

UPDATED REPORT

PATHOLOGICAL DIAGNOSIS:LEFT TEMPORAL LOBE: GLIOBLASTOMA MULTIFORME.

Operation/Specimen: UPDATED REPORT - Left temporal brain

Clinical History and Pre-Op Dx: Tumor

GROSS PATHOLOGY:

SPECIMEN: Left temporal brain tumor

FIXATIVE: Formalin

GENERAL: 3 x 1.5 x 1.5 cm aggregate of brain parenchyma. Cut section
shows an area of hemorrhage 0.8 cm in greatest dimension.

SECTIONS: 1-4- all submitted.

MICROSCOPIC: Sections show a high grade glioma with hypercellularity,
cellular pleomorphism, mitotic figures, capillary proliferation and
patchy areas of palisading necrosis. Portions of uninvolved brain
parenchyma is also present.ADDENDUM: MIB-1 stain shows that the proliferation index of the tumor
cells is about 20%.

TISSUE COMMITTEE CODE:

ICD9: 191.2

BILLING CODES:

Source: NCI Genomic Data Commons file 315538c4-a95d-4691-897b-3bcbe9c33039 (TCGA-06-0142.646FF9FB-C447-4D47-A093-102891F8D4F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).